Somatic mutation profile of tumor specimen TARGET-10-PAREBH-09A (aliquot TARGET-10-PAREBH-09A-01D) from TARGET case TARGET-10-PAREBH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.5 years (6,768 days).
Specimen TARGET-10-PAREBH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58f91f7b-4615-4e73-a921-c67f9719bb19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREBH-10A (Blood Derived Normal), aliquot TARGET-10-PAREBH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/183d9b60-1a19-4168-8f4b-bc8363b0ad59

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 2, Silent 2, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL7R | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.428); catalogued as rs1057519759, COSV57406133; ClinVar: likely pathogenic; called by muse, mutect2
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OTC | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 50/51 reads (98%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.813); catalogued as rs281865553, CM020180; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A5 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs866580929; called by muse, mutect2, varscan2
- LMBR1L | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs777963224; called by muse, mutect2, varscan2
- MAP7D1 | c.1887-5C>T | Splice Region (SNP) | VAF 8/14 reads (57%) | catalogued as rs773290886; called by muse, varscan2
- OR4L1 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as rs201125507, COSV100235970, COSV59850331; called by muse, mutect2, varscan2
- OTOP1 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs759978897; called by muse, varscan2
- COL14A1 | c.1149C>A p.Y383* | Nonsense Mutation (SNP) | VAF 38/60 reads (63%) | called by muse, mutect2, varscan2
- GSE1 | c.2704G>T p.V902L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762084 ACACTGTGTCTCTCGCACAG>TCCT | Missense Mutation (DEL) | VAF 35/40 reads (88%) | called by pindel, varscan2*
- RRAGA | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- SEMA6A | c.1427+1_1427+2insGGA p.X476_splice | Splice Site (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- RBM42 | c.723G>C p.L241= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- SECISBP2 | c.2319C>T p.Y773= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- CDH11 | c.*30C>A | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
